Gene-level copy-number profile of tumor specimen C3N-04157-02 from CPTAC case C3N-04157, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.6 years (22,497 days).
Specimen C3N-04157-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d89ffc69-e823-4af4-8e28-94290d00646e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04157-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/2e21b101-55e6-4cf1-884d-b1c4910c16e6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 4,434; copy number 2: 44,188; copy number 3: 3,768; copy number 4: 6,506; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:29,233,673–29,235,137, 2 genes (within-gene range 0–2): AC061965.2, AC061965.1.
- chr22:21,125,660–21,142,371, 2 genes: POM121L7P, E2F6P2.
- chr22:21,290,760–21,294,586, 1 gene (within-gene range 0–1): BCRP6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:52,985,513–53,106,358, 2 genes, copy number 7: LINC02876, MTCO1P40.

Autosomal genes at a single copy (total copy number 1): 1,581. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
